Surgical pathology report (de-identified scan), TCGA case TCGA-IN-7806, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-7806-01A (Primary Tumor).

HER2 FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE NEGATIVE.

Cells Analyzed: 97

% Hyperdiploid: 28(28.9%)

HER2 IMMUNOPEROXIDASE STUDIES PERFORMED ON THE ADENOCARCINOMA ARE EQUIVOCAL

IHC score: 2+.

This result should be integrated with all clinical and pathologic data in the determination of a comprehensive diagnostic and treatment plan.

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, SUBCARINAL, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 2: LYMPH NODE, POSTERIOR SUBCARINA, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 3: LYMPH NODE, PERIESOPHAGEAL, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 4: ESOPHAGUS AND STOMACH, LAPAROSCOPIC SUBTOTAL ESOPHAGOGASTRECTOMY -
A. MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA WITH SIGNET RING CELL FEATURES,
2.0 CM, ARISING AT THE ESOPHAGOGASTRIC JUNCTION, INVASIVE JUST THROUGH THE MUSCULARIS
PROPRIA INTO THE PERIGASTRIC FAT.
B. SUSPICIOUS FOR ANGIOLYMPHATIC INVASION; NO PERINEURAL INVASION IDENTIFIED.
C. PROXIMAL ESOPHAGEAL AND DISTAL GASTRIC MARGINS ARE NEGATIVE FOR MALIGNANCY.
D. NO TUMOR SEEN IN ONE LYMPH NODE (0/1).
E. PATHOLOGIC STAGING: pT3 N1 (see additional parts).
F. EVIDENCE OF DYSPLASIA IN THE GASTRIC CARDIA; NO EVIDENCE OF BARRETT'S ESOPHAGUS.

PART 5: LYMPH NODES, SUBCARINAL, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 6: LYMPH NODE MID PARAESOPHAGEAL, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 7: LYMPH NODE, PARAESOPHAGEAL NEAR PROXIMAL MARGIN, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 8: LYMPH NODE, SUBCARINAL NEAR AZYGOUS, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 9: LYMPH NODE, SUBCARINAL NEAR LEFT MAIN BRONCHUS, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 10: LYMPH NODE, SUBCARINAL ON ESOPHAGUS, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 11: ADIPOSE TISSUE, GASTROESOPHAGEAL, EXCISION -
METASTATIC CARCINOMA IN ONE OF TWO LYMPH NODES (1/2).

PART 12: LYMPH NODE, GASTRIC, EXCISION -
METASTATIC CARCINOMA IN ONE LYMPH NODE (1/1).

PART 13: LYMPH NODE, PERIGASTRIC, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 14: LYMPH NODE, FAT PAD, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 15: LYMPH NODE, DISTAL PARAESOPHAGEAL, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 16: LYMPH NODE, NEAR GE JUNCTION, EXCISION -
NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

PART 17: ANASTOMOTIC RINGS -
RING OF ESOPHAGUS AND RING OF STOMACH, NO TUMOR SEEN.

PART 18: STOMACH, FINAL GASTRIC MARGIN -
PORTION OF STOMACH, NO TUMOR SEEN.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----
SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Tumor midpoint in distal esophagus AND tumor involves esophagogastric junction
TUMOR SIZE: Greatest dimension: 2.3 cm
Additional dimensions: 1.5 x 0.8 cm

----- MICROSCOPIC -----
HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE:
PATHOLOGIC STAGING (pTNM)

pT3
pN1
Number of lymph nodes examined: 17
Number of lymph nodes involved: 2
pM Not applicable
No prior treatment

PRIOR TREATMENT:
MARGINS

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 55 mm
Specify margin: Proximal
Indeterminate

ANGIOLYMPHATIC INVASION:

ADDITIONAL PATHOLOGIC FINDINGS: Other: Dysplasia within the gastric cardia

Source: NCI Genomic Data Commons file bcdf9f10-9de9-4fc8-9259-f4356aae8813 (TCGA-IN-7806.3D2025E5-85BF-46D2-90B4-0CC8AB50A656.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).